Gene-level copy-number profile of tumor specimen ALCH-B4IS-TTP1-A from ALCHEMIST case ALCH-B4IS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.6 years (24,706 days).
Specimen ALCH-B4IS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a41af2c-6205-4095-a0ed-a796b5a622ce.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4IS-NB2-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/9bebea05-a46f-4e84-b75d-159390b14512

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 202; copy number 2: 52,059; copy number 3: 6,032; copy number 4: 99; copy number 6: 2; copy number 7: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:90,100,236–90,115,402, 2 genes (within-gene range 0–3): IGKV1D-16, IGKV3D-15.
- chr2:90,190,193–90,190,681, 1 gene: IGKV1D-42.
- chr2:130,082,092–130,082,220, 1 gene (within-gene range 0–1): AC018865.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:1,947,278–1,989,920, 2 genes, copy number 7–9: MRPL23, MRPL23-AS1.
- chr22:18,361,820–18,391,105, 2 genes, copy number 6: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 202. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
